Somatic mutation profile of tumor specimen 0DIR1Q from CCDI case PBBVUF, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Embryonal rhabdomyosarcoma, NOS; Tissue or organ of origin: Eyelid; Age at diagnosis: 8.1 years (2,954 days).
Specimen 0DIR1Q: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fcf2f7bf-f0eb-4517-91e1-d591b182ff5b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DIQZO (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ffd52c96-aeb6-42a4-8e1d-496bbf1d6f6b

The open-access MAF lists 42 somatic variants for this specimen: 29 protein-altering or splice-affecting, 10 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 26, Silent 10, Frame Shift Del 1, 5'Flank 1, Nonsense Mutation 1, Splice Site 1, Intron 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR4 | c.1648G>C p.V550L | Missense Mutation (SNP) | VAF 338/703 reads (48%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV52800715, COSV52802492, COSV52804538; called by muse, mutect2, varscan2
- PTPN11 | c.215C>T p.A72V | Missense Mutation (SNP) | VAF 147/762 reads (19%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.806); catalogued as rs121918454, CM013417, COSV61005613, COSV61008344, COSV61012146; ClinVar: likely pathogenic / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- CDH24 | c.2204C>T p.P735L | Missense Mutation (SNP) | VAF 89/366 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as rs1191073727; called by muse, mutect2, varscan2
- CHST13 | c.607C>T p.R203C | Missense Mutation (SNP) | VAF 124/558 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as COSV60041330; called by muse, mutect2, varscan2
- CSMD1 | c.2156C>T p.S719L (on ENST00000520002; = p.S718L on NM_033225.6) | Missense Mutation (SNP) | VAF 170/1796 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as rs752005533, COSV59288966; called by muse, mutect2
- DCAF11 | c.1591G>A p.A531T | Missense Mutation (SNP) | VAF 64/373 reads (17%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0); catalogued as rs746796439; called by muse, mutect2, varscan2
- DCAF4L2 | c.946G>A p.A316T | Missense Mutation (SNP) | VAF 157/1037 reads (15%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.986); catalogued as COSV60480325; called by muse, mutect2, varscan2
- DDI1 | c.323G>A p.R108H | Missense Mutation (SNP) | VAF 65/392 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.306); catalogued as rs138983347, COSV56380960; called by muse, mutect2, varscan2
- F8 | c.65G>T p.R22I | Missense Mutation (SNP) | VAF 166/1494 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM020407, CM055176; called by muse, mutect2, varscan2
- LIPE | c.1285G>A p.A429T | Missense Mutation (SNP) | VAF 56/255 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.448); catalogued as rs371718921; called by muse, mutect2, varscan2
- MRPS35 | c.113-1G>A p.X38_splice | Splice Site (SNP) | VAF 209/982 reads (21%) | catalogued as rs771760529; called by muse, mutect2, varscan2
- MUC12 | c.2476G>A p.V826I (on ENST00000379442; = p.V683I on NM_001164462.1) | Missense Mutation (SNP) | VAF 70/1161 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.101); catalogued as rs1331338172, COSV65197129, COSV65203700; called by muse, mutect2
- MUC17 | c.692C>A p.S231* | Nonsense Mutation (SNP) | VAF 42/722 reads (6%) | catalogued as COSV100073255; called by muse, mutect2
- SERPINI2 | c.961A>T p.T321S | Missense Mutation (SNP) | VAF 199/946 reads (21%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.997); catalogued as COSV52988685; called by mutect2, varscan2
- SPANXD | c.160C>T p.R54C | Missense Mutation (SNP) | VAF 562/1449 reads (39%) | SIFT tolerated (0.19); PolyPhen benign (0.013); catalogued as rs373261190, COSV65152935; called by muse, mutect2, varscan2
- VPS13D | c.5807G>A p.R1936Q | Missense Mutation (SNP) | VAF 178/763 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as rs747867326, COSV99165516, COSV99167371; called by muse, mutect2, varscan2
- BARD1 | c.714del p.K238Nfs*17 | Frame Shift Del (DEL) | VAF 230/1108 reads (21%) | called by mutect2, varscan2
- CAMTA1 | c.2326C>A p.L776M | Missense Mutation (SNP) | VAF 105/453 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CCT4 | c.82G>A p.D28N | Missense Mutation (SNP) | VAF 112/484 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.083); called by muse, mutect2, varscan2
- DAGLB | c.322G>A p.E108K | Missense Mutation (SNP) | VAF 172/813 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GAD2 | c.1463G>A p.R488Q | Missense Mutation (SNP) | VAF 243/1031 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.872); called by muse, mutect2, varscan2
- MED12 | c.3332A>T p.N1111I | Missense Mutation (SNP) | VAF 27/780 reads (3%) | SIFT tolerated (0.36); PolyPhen benign (0.417); called by muse, mutect2
- NKRF | c.482C>T p.T161I | Missense Mutation (SNP) | VAF 189/792 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.278); called by muse, mutect2, varscan2
- NXN | c.750G>A p.M250I | Missense Mutation (SNP) | VAF 90/335 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- PLCB3 | c.2522A>G p.Y841C | Missense Mutation (SNP) | VAF 90/667 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SLC5A4 | c.682G>T p.G228C | Missense Mutation (SNP) | VAF 209/725 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SOX7 | c.565G>A p.G189S | Missense Mutation (SNP) | VAF 60/339 reads (18%) | SIFT tolerated (0.45); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- TCEANC | c.563C>T p.S188F (on ENST00000380600 / NM_001297563.2; = p.S218F on NM_152634.4) | Missense Mutation (SNP) | VAF 210/965 reads (22%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- ZDBF2 | c.3098A>G p.N1033S | Missense Mutation (SNP) | VAF 69/1525 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- AFF2 | c.969C>G p.L323= | Silent (SNP) | VAF 215/1212 reads (18%) | catalogued as COSV100651399; called by muse, mutect2, varscan2
- C1QC | c.573C>T p.T191= | Silent (SNP) | VAF 110/585 reads (19%) | catalogued as COSV101009514; called by muse, mutect2, varscan2
- CD33 | c.552C>T p.P184= | Silent (SNP) | VAF 19/560 reads (3%) | called by muse, mutect2
- CST8 | c.36C>A p.L12= | Silent (SNP) | VAF 125/768 reads (16%) | catalogued as COSV55671213; called by muse, mutect2, varscan2
- DGKZ | c.3054C>T p.H1018= (on ENST00000454345 / NM_001105540.2; = p.H830= on NM_003646.4) | Silent (SNP) | VAF 243/685 reads (35%) | catalogued as rs772872206; called by muse, mutect2, varscan2
- ELAVL4 | c.795C>G p.P265= | Silent (SNP) | VAF 160/749 reads (21%) | catalogued as rs375707512; called by muse, mutect2, varscan2
- FGD1 | c.897C>T p.F299= | Silent (SNP) | VAF 77/328 reads (23%) | catalogued as COSV100911253; called by muse, mutect2, varscan2
- LY75 | c.672G>A p.E224= | Silent (SNP) | VAF 110/1580 reads (7%) | catalogued as rs1203251794; called by muse, mutect2
- OR2A12 | c.768C>T p.V256= | Silent (SNP) | VAF 42/685 reads (6%) | catalogued as rs1563043042; called by muse, mutect2
- OR6B2 | c.69G>T p.L23= | Silent (SNP) | VAF 145/763 reads (19%) | catalogued as rs745484824; called by mutect2, varscan2
- CIP2A | chr3:108589441 C>G | 5'Flank (SNP) | VAF 20/86 reads (23%) | catalogued as rs1424902798; called by muse, mutect2, varscan2
- FCER2 | c.317-67C>A | Intron (SNP) | VAF 22/105 reads (21%) | called by muse, mutect2, varscan2
- KIR2DL3 | c.*100T>C | 3'UTR (SNP) | VAF 22/346 reads (6%) | catalogued as rs1291648264; called by muse, mutect2
